TARGET case TARGET-15-SJMPAL044950 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/42d19f0c-ddef-4f1d-a2d5-242ee758c131

Demographics
Sex at birth: male; Age at index: 0 years; Vital status: Dead; Days to death: 301 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.1 years (41 days); Year of diagnosis: 2012; Days to last follow up: 301 days.

Follow-up (1 entry)
- Days to follow up: 301 days; Event-free: no event (relapse, second malignancy or death) recorded through day 301; Year of follow up: 2013.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 244 ×10³/µL.

Biospecimens (2 samples)
- Sample TARGET-15-SJMPAL044950-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL044950-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 301
- Protocol: AIEOP
- WBC at Diagnosis: 244.3
- Initial Therapy: Interfant06
- Karyotype: t(4;11)
- WHO ALAL Classification: MLL
- WHO Dx: MLL
